Somatic mutation profile of tumor specimen TCGA-DU-7301-01A (aliquot TCGA-DU-7301-01A-11D-2086-08) from TCGA case TCGA-DU-7301, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 53.8 years (19,644 days).
Specimen TCGA-DU-7301-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e60404ca-c56f-41b7-8917-b67748dc4fe4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7301-10A (Blood Derived Normal), aliquot TCGA-DU-7301-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b18945b7-5538-4571-94b2-2b6f2c366114

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 16, Silent 4, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP43 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs376788209; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 42/129 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 80/86 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1555526268, CM971503, COSV52676850, COSV52715987, COSV52740951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMACR | c.968T>C p.V323A | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56875833; called by muse, mutect2, varscan2
- CHEK2 | c.1567G>A p.A523T (on ENST00000382580 / NM_001005735.2; = p.A480T on NM_007194.4) | Missense Mutation (SNP) | VAF 114/272 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs773600515, COSV60427060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLEC9A | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63351765; called by muse, mutect2
- EEF1A1 | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV100303485; called by muse, mutect2, varscan2
- FAM117A | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs771153493, COSV53634167; called by muse, mutect2, varscan2
- GOLGA4 | c.5732A>G p.H1911R | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs779135798, COSV62714179; called by muse, mutect2, varscan2
- MAPK12 | c.933C>G p.F311L | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.996); catalogued as COSV53136118, COSV99299327; called by muse, mutect2, varscan2
- NEB | c.16813G>A p.A5605T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1289511955, COSV51177020, COSV99427165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10C1 | c.284G>A p.R95H (on ENST00000622521; = p.R93H on NM_013941.3) | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1324923117, COSV65823749; called by muse, mutect2, varscan2
- OR4A16 | c.460T>G p.S154A | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.122); catalogued as COSV59045293; called by muse, mutect2
- PDE6C | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV65117931; called by muse, mutect2, varscan2
- PPFIA4 | c.2201C>G p.P734R (on ENST00000447715; = p.P735R on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV55322191; called by muse, mutect2, varscan2
- TMC4 | c.491_493del p.F164del (on ENST00000617472 / NM_001145303.3; = p.F158del on NM_144686.4) | In Frame Del (DEL) | VAF 7/8 reads (88%) | catalogued as rs770372525; called by mutect2, varscan2
- TRPC6 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 83/235 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs371919016, COSV60256337; called by muse, mutect2, varscan2
- ZNF425 | c.274A>T p.M92L | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65202825; called by muse, mutect2
- ATRX | c.2476_2477del p.K826Efs*4 | Frame Shift Del (DEL) | VAF 52/78 reads (67%) | called by mutect2, pindel, varscan2
- DHX30 | c.1463_1465del p.I488del (on ENST00000445061 / NM_138615.3; = p.I449del on NM_014966.3) | In Frame Del (DEL) | VAF 76/205 reads (37%) | called by pindel, varscan2
- DHX35 | c.20del p.P7Rfs*2 | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | called by mutect2, pindel, varscan2
- FSTL5 | c.547del p.M183Cfs*13 | Frame Shift Del (DEL) | VAF 41/79 reads (52%) | called by mutect2, pindel, varscan2
- ARHGEF1 | c.309C>T p.F103= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs782384716, COSV61529811; called by muse, mutect2, varscan2
- DOCK7 | c.3655T>C p.L1219= (on ENST00000635253 / NM_001367561.1; = p.L1188= on NM_033407.3) | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as COSV52022652; called by muse, mutect2, varscan2
- FBXO43 | c.1809A>G p.G603= | Silent (SNP) | VAF 68/134 reads (51%) | catalogued as COSV71055675, COSV71055732; called by muse, mutect2, varscan2
- MEGF8 | c.3585G>A p.R1195= (on ENST00000251268 / NM_001271938.2; = p.R1128= on NM_001410.3) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV52103168; called by muse, mutect2, varscan2
